Somatic mutation profile of tumor specimen TCGA-DD-A39W-01A (aliquot TCGA-DD-A39W-01A-11D-A20W-10) from TCGA case TCGA-DD-A39W, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 29.3 years (10,699 days).
Specimen TCGA-DD-A39W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fddc7718-5cff-4ea5-bf2b-fbc67b3d6d0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A39W-11A (Solid Tissue Normal), aliquot TCGA-DD-A39W-11A-11D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8607bf36-8856-48fe-899b-7a11ed2c0403

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 11, Nonsense Mutation 3, Splice Site 3, Frame Shift Del 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.3424C>T p.Q1142* | Nonsense Mutation (SNP) | VAF 72/179 reads (40%) | hotspot (GDC flag); catalogued as COSV61371666; called by muse, mutect2, varscan2
- ABCC8 | c.3144G>T p.R1048S | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100217744; called by muse, mutect2, varscan2
- ADAM28 | c.385G>T p.G129C | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99739876; called by muse, mutect2
- ADAM28 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1410910068, COSV99739879; called by muse, mutect2
- ARAP3 | c.1386-2A>T p.X462_splice | Splice Site (SNP) | VAF 7/146 reads (5%) | catalogued as COSV99500302; called by muse, mutect2
- BICDL2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.775); catalogued as rs758906156, COSV66370257; called by muse, mutect2, varscan2
- CAPNS1 | c.605-1G>C p.X202_splice | Splice Site (SNP) | VAF 7/54 reads (13%) | catalogued as COSV99497156; called by muse, mutect2, varscan2
- CTCF | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.295); catalogued as rs1259626314, COSV99866624; called by muse, mutect2, varscan2
- DCHS1 | c.5896C>T p.R1966C | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs1050619250, COSV55032765; called by muse, mutect2, varscan2
- DHX9 | c.2440G>A p.G814S | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as COSV100841528; called by muse, mutect2, varscan2
- EME1 | c.341A>G p.D114G | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV99869155; called by muse, mutect2, varscan2
- FOLH1 | c.31G>C p.A11P | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.057); catalogued as COSV99923968; called by muse, mutect2, varscan2
- FTSJ3 | c.1763A>G p.Q588R | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100835085; called by muse, mutect2, varscan2
- HKDC1 | c.1370C>T p.T457I | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100664788; called by muse, mutect2, varscan2
- HNF1A | c.628T>A p.S210T | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV99983030; called by muse, mutect2, varscan2
- HPS3 | c.1245+1G>A p.X415_splice | Splice Site (SNP) | VAF 18/102 reads (18%) | catalogued as COSV99937654; called by muse, mutect2, varscan2
- ITGB4 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.081); catalogued as rs569235037, COSV52332454; called by muse, mutect2, varscan2
- LHFPL6 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1440185312, COSV101095682; called by muse, mutect2, varscan2
- OR2J3 | c.430T>G p.C144G | Missense Mutation (SNP) | VAF 123/307 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101013664; called by muse, mutect2, varscan2
- PCDHA9 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 50/369 reads (14%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.003); catalogued as COSV100970124; called by muse, varscan2
- PCDHB12 | c.1330G>A p.V444I | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.066); catalogued as COSV53392722, COSV53398469; called by muse, mutect2
- PPARA | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV53079399, COSV99415929; called by muse, mutect2, varscan2
- RNF214 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as rs377377564; called by muse, mutect2, varscan2
- RPS6KA3 | c.173A>T p.E58V | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV101084669; called by muse, mutect2, varscan2
- SAMD5 | c.75C>A p.N25K | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100822572; called by muse, mutect2, varscan2
- WDR45B | c.647C>G p.S216* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV101124471; called by muse, mutect2, varscan2
- WFDC5 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100332213; called by muse, mutect2, varscan2
- YWHAE | c.314A>G p.D105G | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV99981580; called by muse, mutect2
- ZNF583 | c.494T>G p.F165C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV99382320; called by muse, mutect2, varscan2
- KRTAP5-3 | c.206C>A p.S69Y | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- STEAP3 | c.1162del p.W388Gfs*18 | Frame Shift Del (DEL) | VAF 36/103 reads (35%) | called by mutect2, pindel, varscan2
- CCDC88A | c.522A>G p.Q174= | Silent (SNP) | VAF 42/247 reads (17%) | catalogued as COSV99711227; called by muse, mutect2, varscan2
- CD1B | c.432C>A p.V144= | Silent (SNP) | VAF 81/246 reads (33%) | catalogued as COSV100939307; called by muse, mutect2, varscan2
- CSMD1 | c.1677G>A p.E559= (on ENST00000520002; = p.E558= on NM_033225.6) | Silent (SNP) | VAF 50/103 reads (49%) | catalogued as COSV100153901; called by muse, mutect2, varscan2
- ELL2 | c.1911G>A p.E637= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV99427918; called by muse, mutect2, varscan2
- GABPA | c.1236G>A p.A412= | Silent (SNP) | VAF 82/207 reads (40%) | catalogued as rs563533466, COSV61397329; called by muse, mutect2, varscan2
- IRAG1 | c.2385C>T p.T795= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV101351734; called by muse, mutect2
- LIG3 | c.372C>T p.P124= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99253193; called by muse, mutect2, varscan2
- MAL | c.243G>A p.E81= | Silent (SNP) | VAF 59/166 reads (36%) | catalogued as COSV59430879; called by muse, mutect2, varscan2
- MUC17 | c.12246G>A p.T4082= | Silent (SNP) | VAF 38/178 reads (21%) | catalogued as rs201108444, COSV100072640; called by muse, mutect2, varscan2
- OR12D3 | c.414G>A p.V138= | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as rs755840622, COSV101011480; called by muse, mutect2, varscan2
- PCDHGA5 | c.264C>T p.G88= | Silent (SNP) | VAF 51/144 reads (35%) | catalogued as COSV99547314; called by muse, mutect2, varscan2
- MIR520D | n.77A>G | RNA (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- PHPT1 | c.286-255_286-249del | Intron (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
